Surgical pathology report (de-identified scan), TCGA case TCGA-61-1737, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-1737-01A (Primary Tumor).

[page 1 of 2]
FINAL DIAGNOSIS:

PART 1: OMENTUM, BIOPSY AND FROZEN SECTION –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 2: SOFT TISSUE, LEFT PELVIC SIDEWALL, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA –

PART 3: SOFT TISSUE, POSTERIOR CUL-DE-SAC, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 4: UTERUS WITH BOTH OVARIES AND FALLOPIAN TUBES, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY (186 GRAMS) –

- A. POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA INVOLVING RIGHT AND LEFT OVARIES WITH MULTIPLE METASTATIC TUMOR NODULES INVOLVING UTERINE SEROSA AND PENETRATING INTO THE OUTER PORTION OF THE MYOMETRIUM WITH EXTENSIVE LYMPHOVASCULAR PERMEATION.
- B. ACUTE AND CHRONIC CYSTIC CERVICITIS WITH SQUAMOUS METAPLASIA.
- C. ENDOMETRIUM WITH DECIDUALIZED STROMA AND MIXED GLAND (SECRETORY AND INACTIVE).
- D. MYOMETRIUM WITH MICROSCOPIC (0.2 CM) LEIOMYOMA AND METASTATIC TUMOR INVOLVING OUTER PORTION OF MYOMETRIUM WITH LYMPHOVASCULAR PERMEATION.
- E. UTERINE SEROSA WITH MULTIFOCAL METASTATIC SEROUS ADENOCARCINOMA.
- F. RIGHT AND LEFT FALLOPIAN TUBES TUBE, NO TUMOR SEEN.
- G. RIGHT AND LEFT OVARIES WITH POORLY DIFFERENTIATED PAPILLARY SEROUS ADENOCARCINOMA.
- H. LEFT OVARY WITH HEMORRHAGIC CORPUS LUTEUM.
- I. PARAOVARIAN TISSUE WITH ENDOSALPINGIOSIS.

PART 5: SOFT TISSUE, PELVIC SIDEWALL, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 6: APPENDIX, APPENDECTOMY –

- A. METASTATIC SEROUS ADENOCARCINOMA WITH EXTENSIVE LYMPHOVASCULAR PERMEATION INVOLVING SEROSA AND MUSCULARIS PROPRIA.
- B. FIBROUS OBLITERATION OF TIP.

PART 7: LARGE BOWEL, PARTIAL COLECTOMY –

- A. METASTATIC SEROUS ADENOCARCINOMA WITH LYMPHOVASCULAR PERMEATION INVOLVING SEROSA AND MUSCULARIS PROPRIA.
- B. ONE REGIONAL LYMPH NODE WITH METASTATIC ADENOCARCINOMA (1/1).

PART 8: SOFT TISSUE, RIGHT UPPER QUADRANT, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 9: SOFT TISSUE, MESENTERIC NODULE, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 10: SOFT TISSUE, ANTERIOR ABDOMINAL WALL, BIOPSY –

METASTATIC POORLY DIFFERENTIATED SEROUS ADENOCARCINOMA.

PART 11: LYMPH NODES, LEFT COMMON ILEAC, BIOPSY –

ONE LYMPH NODE, FREE OF TUMOR (0/1).

PART 12: LYMPH NODE, LEFT OBTURATOR, BIOPSY –

METASTATIC SEROUS ADENOCARCINOMA INVOLVING ONE LYMPH NODE (1/1), UP TO 1.4 CM.

PART 13: LYMPH NODE, RIGHT OBTURATOR, BIOPSY –

METASTATIC SEROUS ADENOCARCINOMA INVOLVING FOUR OUT OF FIVE LYMPH NODES (4/5), UP TO 1.6 CM WITH EXTRACAPSULAR EXTENSION.

PART 14: LYMPH NODES, RIGHT COMMON ILIAC, BIOPSY –

METASTATIC SEROUS ADENOCARCINOMA INVOLVING TWO OUT OF TWO LYMPH NODES (2/2), UP TO 1.6 CM WITH LYMPHOVASCULAR PERMEATION IN THE ADJACENT ADIPOSE TISSUE.

PART 15: LYMPH NODES, RIGHT PERIAORTIC, BIOPSY –

METASTATIC SEROUS ADENOCARCINOMA INVOLVING TWO OUT OF TWO LYMPH NODES (2/2), UP TO 1.8 CM.

[page 2 of 2]
MICROSCOPIC:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:	Bilateral
PROCEDURE:	TAH with salpingo-oophorectomy
TUMOR SIZE:	Maximum dimension: 4.2 cm
TUMOR TYPE:	Papillary serous carcinoma
HISTOLOGIC SILVERBERG GRADE:	Poorly differentiated (8-9 pts)
ARCHITECTURAL PATTERN:	Solid (3)
CYTOLOGIC ATYPIA:	Marked (3)
MITOTIC COUNTS / 10hpf:	10-24 (2)
VASCULAR INVASION:	Yes
TUMOR CAPSULE:	Ruptured
SURFACE IMPLANTS:	Invasive
SURFACE IMPLANT SITE:	Uterus, Omentum, Peritoneal metastasis beyond the pelvis
SURFACE IMPLANT SIZE:	> 2 cm.
ASSOCIATED OTHER LESION:	Surface epithelial inclusion
MALIGNANT CELLS IN ASCITES OR PERITONEAL WASHING:	Yes
LYMPH NODES EXAMINED:	Total number of lymph nodes examined: 11
LYMPH NODES POSITIVE:	Number of positive lymph nodes, Right: 8 Number of positive lymph nodes, Left: 1
LYMPH NODE GROUPS INVOLVED:	Obturator, Right, Obturator, Left, Common iliac, Right, Para-aortic, Right
EXTRANODAL EXTENSION:	Yes
T STAGE, PATHOLOGIC:	pT3c
N STAGE, PATHOLOGIC:	pN1
M STAGE, PATHOLOGIC:	pM1
FIGO STAGE:	IV

Source: NCI Genomic Data Commons file f9ad8af5-24e5-4e26-9c3f-e1a5fc0ff0ef (TCGA-61-1737.2FA09BF8-8BE5-411C-A9CF-16C12ED1390F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).